Somatic mutation profile of tumor specimen C3L-09616-02 (aliquot CPT0492630006) from CPTAC case C3L-09616, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.1 years (19,764 days).
Specimen C3L-09616-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b582108f-3a22-4bea-bfe6-4eef5b9e94df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09616-31 (Blood Derived Normal), aliquot CPT0492680004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/586c1ff0-6d6c-4648-8b95-7b73e82096ec

The open-access MAF lists 301 somatic variants for this specimen: 193 protein-altering or splice-affecting, 98 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 98, Nonsense Mutation 12, Intron 6, Splice Site 3, Splice Region 2, 3'UTR 1, 5'UTR 1, In Frame Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 229/417 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 318/484 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as CM034218, CM095540, COSV58683071, COSV58683670; called by muse, mutect2, varscan2
- AATK | c.1696G>A p.G566S (on ENST00000326724 / NM_001080395.3; = p.G463S on NM_004920.2) | Missense Mutation (SNP) | VAF 258/688 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1171952527, COSV58364226; called by muse, varscan2
- ABCC6 | c.3669G>A p.W1223* | Nonsense Mutation (SNP) | VAF 180/448 reads (40%) | catalogued as rs1173994952; called by muse, mutect2, varscan2
- ADD2 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 177/485 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs782468498; called by muse, mutect2, varscan2
- ARFGEF1 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51618901; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 104/304 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- BBOF1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs748900725; called by muse, mutect2, varscan2
- CA13 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 111/314 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391307599; called by muse, mutect2, varscan2
- CACNA1E | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 147/408 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100701398; called by muse, mutect2, varscan2
- CATSPERG | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 219/284 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53053267; called by muse, mutect2, varscan2
- CCDC166 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 244/633 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1554616972; called by muse, mutect2, varscan2
- CD80 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 182/466 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51802084; called by muse, mutect2, varscan2
- CEP192 | c.3700C>T p.H1234Y | Missense Mutation (SNP) | VAF 205/540 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336741406, COSV58061107; called by muse, mutect2
- COL1A2 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 165/264 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM088317; called by muse, mutect2, varscan2
- CRP | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 115/341 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.68); catalogued as rs200949626, COSV54814574; called by muse, mutect2, varscan2
- CSF2RB | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 206/560 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759650297; called by muse, varscan2
- CSMD1 | c.9122C>T p.P3041L (on ENST00000520002; = p.P3040L on NM_033225.6) | Missense Mutation (SNP) | VAF 97/168 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1467515940; called by muse, varscan2
- DGKK | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 146/177 reads (82%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV101053085; called by muse, mutect2, varscan2
- DNAH14 | c.5566C>T p.Q1856* (on ENST00000445597; = p.Q2277* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 60/201 reads (30%) | catalogued as rs867115567; called by muse, mutect2, varscan2
- DNAH5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 142/394 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs779957324, COSV54206424; called by muse, mutect2, varscan2
- DNAH9 | c.7013C>T p.P2338L | Missense Mutation (SNP) | VAF 163/239 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV52336030; called by muse, mutect2, varscan2
- DSCAM | c.5681G>A p.R1894Q | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1453514770, COSV101259771; called by muse, mutect2, varscan2
- EHMT2 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 558/1082 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs750403350, COSV64997165; called by muse, mutect2, varscan2
- EML2 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 338/445 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1466778775, COSV55600294; called by muse, mutect2, varscan2
- FARP2 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 109/291 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745488423, COSV50870261, COSV99884852; called by muse, mutect2, varscan2
- FYTTD1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as rs201112902; called by muse, mutect2, varscan2
- GALNT8 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 146/450 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52899378; called by muse, mutect2
- GDPGP1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 134/560 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.051); catalogued as COSV61576115; called by muse, mutect2, varscan2
- GLT8D1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 111/188 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1335432952, COSV99803832; called by muse, mutect2, varscan2
- HSF1 | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 191/470 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1554845957; called by muse, mutect2, varscan2
- HYDIN | c.4588G>A p.D1530N | Missense Mutation (SNP) | VAF 112/330 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs79049769, COSV66856452, COSV66889367; called by muse, mutect2, varscan2
- KCNH5 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 173/391 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100525940; called by muse, mutect2, varscan2
- KCNH8 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as COSV60471990; called by muse, mutect2, varscan2
- KLF12 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV66569143; called by muse, mutect2, varscan2
- KPRP | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 143/389 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV64220894; called by muse, mutect2, varscan2
- LHCGR | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54302536; called by muse, mutect2, varscan2
- LIMCH1 | c.3218G>A p.R1073Q | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1393633123, COSV58294365; called by muse, mutect2, varscan2
- LRP1B | c.10774C>T p.P3592S | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs1553455636; called by muse, mutect2, varscan2
- LRP1B | c.9967C>T p.R3323C | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1328117748, COSV67187455; called by muse, mutect2, varscan2
- MAGEA10 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 235/296 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV54882887; called by muse, mutect2, varscan2
- MMP16 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 163/458 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.366); catalogued as COSV54182863, COSV54192050; called by muse, mutect2, varscan2
- MON2 | c.4861C>T p.R1621C | Missense Mutation (SNP) | VAF 125/334 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs375029048; called by muse, mutect2, varscan2
- MSRB3 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 143/397 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267603630, COSV57589447; called by muse, mutect2, varscan2
- MUC16 | c.33573G>A p.M11191I | Missense Mutation (SNP) | VAF 184/445 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV67493910; called by muse, mutect2, varscan2
- MUC16 | c.21262C>T p.P7088S | Missense Mutation (SNP) | VAF 183/517 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV67473965; called by muse, mutect2, varscan2
- MUC5B | c.2995G>A p.G999R | Missense Mutation (SNP) | VAF 165/469 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs753096895; called by muse, mutect2, varscan2
- NDUFAF5 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 164/430 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65246605; called by muse, mutect2, varscan2
- NFASC | c.1024G>A p.E342K (on ENST00000339876 / NM_001378329.1; = p.E353K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs1395051180, COSV58379240; called by muse, mutect2, varscan2
- NOTCH2 | c.2815C>T p.P939S | Missense Mutation (SNP) | VAF 112/309 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV56695063; called by muse, mutect2, varscan2
- NRF1 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 112/448 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774042493, COSV99781685; called by muse, mutect2, varscan2
- OR10K1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV56870588; called by muse, mutect2, varscan2
- OR13C9 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 129/207 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52241415; called by muse, mutect2, varscan2
- OR14I1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 153/428 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61199000, COSV61199650; called by muse, mutect2, varscan2
- OR2T27 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 135/682 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs267598515; called by muse, mutect2, varscan2
- OR4A8 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs781400381; called by muse, mutect2, varscan2
- OR51E2 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 165/444 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV67808341; called by muse, mutect2, varscan2
- OR5D13 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs777810747, COSV62333146, COSV62334912, COSV62335581; called by muse, mutect2, varscan2
- OR6K6 | c.470C>T p.P157L (on ENST00000368144; = p.P133L on NM_001005184.1) | Missense Mutation (SNP) | VAF 217/505 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770663048; called by muse, mutect2, varscan2
- OR6V1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 254/907 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs867782093, COSV69237344; called by muse, mutect2, varscan2
- OTOG | c.6747C>T p.C2249= | Splice Region (SNP) | VAF 106/323 reads (33%) | catalogued as rs562749083; called by muse, varscan2
- P2RY1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 184/472 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59310135; called by muse, mutect2, varscan2
- PADI1 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 148/434 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433246369; called by muse, mutect2
- PAPPA2 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 188/532 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV62807676; called by muse, mutect2, varscan2
- PCDHB6 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 191/461 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV50694999, COSV99170729; called by muse, mutect2, varscan2
- PCDHB8 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs1554280864; called by muse, mutect2, varscan2
- PCDHGB1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV53942197; called by muse, mutect2, varscan2
- PCLO | c.9425C>T p.S3142L | Missense Mutation (SNP) | VAF 177/293 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs868457640, COSV61656328; called by muse, mutect2, varscan2
- PDE1A | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV59517796; called by muse, mutect2, varscan2
- PELP1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 101/172 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1379000445, COSV99342536; called by muse, mutect2, varscan2
- PLPPR3 | c.1465G>A p.G489R (on ENST00000520876 / NM_001270366.2; = p.G517R on NM_024888.2) | Missense Mutation (SNP) | VAF 234/684 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1470095894; called by muse, mutect2
- POLR1B | c.3040A>G p.T1014A | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54494275; called by muse, mutect2, varscan2
- PRDM9 | c.1832G>A p.R611K | Missense Mutation (SNP) | VAF 251/670 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.062); catalogued as COSV99690141; called by muse, mutect2, varscan2
- PRKN | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1006331297; called by muse, mutect2, varscan2
- PRRT4 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 352/643 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs956134641, COSV101435676; called by muse, mutect2, varscan2
- PTCHD4 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 373/626 reads (60%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs1425563930, COSV59778294; called by muse, mutect2, varscan2
- PXDNL | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 224/545 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs760447314; called by muse, mutect2, varscan2
- RBM46 | c.1547A>G p.N516S | Missense Mutation (SNP) | VAF 176/440 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs763225278; called by muse, mutect2, varscan2
- RHOG | c.141C>G p.D47E | Missense Mutation (SNP) | VAF 223/643 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as rs369419390; called by muse, mutect2, varscan2
- RNASE12 | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 149/339 reads (44%) | catalogued as rs868043954; called by muse, mutect2, varscan2
- SEMA5B | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 191/516 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1289398519, COSV52109160; called by muse, mutect2, varscan2
- SGSM1 | c.3046G>A p.G1016R (on ENST00000400359 / NM_001039948.4; = p.G955R on NM_133454.3) | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167860576, COSV68508979; called by muse, mutect2, varscan2
- SLC10A2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs201821506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC2A11 | c.424C>T p.Q142* (on ENST00000345044 / NM_001024938.4; = p.Q149* on NM_030807.5) | Nonsense Mutation (SNP) | VAF 124/342 reads (36%) | catalogued as rs867795790; called by muse, mutect2, varscan2
- SLC30A6 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 161/407 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.462); catalogued as rs771594616; called by muse, mutect2, varscan2
- SLC47A1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 146/240 reads (61%) | SIFT tolerated (0.37); PolyPhen benign (0.241); catalogued as COSV104374306; called by muse, varscan2
- SLCO1C1 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 141/412 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV56872448; called by muse, mutect2, varscan2
- SLCO6A1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV65808522; called by muse, mutect2, varscan2
- SMR3B | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 137/339 reads (40%) | PolyPhen benign (0.087); catalogued as COSV100513400, COSV59229034; called by muse, mutect2, varscan2
- SSUH2 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs776971510, COSV58033058; called by muse, mutect2, varscan2
- ST18 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 110/324 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52511395; called by muse, mutect2, varscan2
- ST8SIA4 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 151/368 reads (41%) | PolyPhen possibly damaging (0.885); catalogued as rs148751339; called by muse, mutect2, varscan2
- STEAP4 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 175/277 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs769390918, COSV57329004; called by muse, mutect2, varscan2
- SUMO3 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 139/378 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV60538218; called by muse, mutect2, varscan2
- SUPT3H | c.679G>A p.V227I (on ENST00000371460 / NM_181356.3; = p.V216I on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 138/558 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1242461092; called by muse, mutect2, varscan2
- TACR3 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 129/347 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as COSV59203596; called by muse, mutect2, varscan2
- TEX15 | c.7472C>T p.S2491F (on ENST00000256246; = p.S2874F on NM_001350162.2) | Missense Mutation (SNP) | VAF 143/237 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV56341016; called by muse, mutect2, varscan2
- TRIML2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 142/231 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV58716025; called by muse, mutect2, varscan2
- UNC13C | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as rs1369385841, COSV52907755; called by muse, mutect2, varscan2
- USH2A | c.15085G>A p.G5029R | Missense Mutation (SNP) | VAF 127/360 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1359233931; called by muse, mutect2, varscan2
- VCAN | c.5588A>G p.E1863G | Missense Mutation (SNP) | VAF 135/351 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs763250958; called by muse, mutect2, varscan2
- VSIG2 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764844490, COSV52518261; called by muse, varscan2
- ZNF407 | c.4439C>T p.P1480L | Missense Mutation (SNP) | VAF 163/430 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751685268, COSV99997008; called by muse, mutect2
- A1CF | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 127/361 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AC013477.1 | c.2488C>T p.Q830* | Nonsense Mutation (SNP) | VAF 97/301 reads (32%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.1515G>A p.W505* | Nonsense Mutation (SNP) | VAF 157/396 reads (40%) | called by muse, mutect2, varscan2
- ADGB | c.4496G>A p.G1499E | Missense Mutation (SNP) | VAF 154/372 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ADGRB1 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 254/688 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AFM | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 98/260 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANAPC5 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANK3 | c.7478C>T p.S2493L | Missense Mutation (SNP) | VAF 167/489 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AP4S1 | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ARMC4 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 109/185 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ARRDC2 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 180/525 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BIRC6 | c.4870A>T p.M1624L | Missense Mutation (SNP) | VAF 149/400 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CABIN1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 158/408 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CCDC166 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 240/664 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD3G | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 84/290 reads (29%) | called by muse, mutect2
- CDC25C | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 135/359 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CFAP54 | c.9088G>A p.E3030K | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP92 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHD8 | c.6199G>A p.D2067N (on ENST00000646647 / NM_001170629.2; = p.D1788N on NM_020920.4) | Missense Mutation (SNP) | VAF 176/466 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- CIZ1 | c.1291_1314del p.T431_Q438del | In Frame Del (DEL) | VAF 160/276 reads (58%) | called by mutect2, pindel, varscan2
- CKAP2 | c.376C>G p.Q126E (on ENST00000378037 / NM_001098525.2; = p.Q125E on NM_018204.5) | Missense Mutation (SNP) | VAF 105/163 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COL6A6 | c.4781G>A p.G1594E | Missense Mutation (SNP) | VAF 142/434 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLGALT1 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- CPD | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CPXM2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 123/296 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CRNKL1 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 148/426 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- CYP2C18 | c.819G>A p.Q273= | Splice Region (SNP) | VAF 58/185 reads (31%) | called by muse, mutect2, varscan2
- DEPDC5 | c.2383A>G p.T795A (on ENST00000400246; = p.T864A on NM_014662.5) | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMP1 | c.208A>C p.T70P | Missense Mutation (SNP) | VAF 142/390 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH12 | c.2750C>T p.P917L (on ENST00000351747; = p.P940L on NM_001366028.2) | Missense Mutation (SNP) | VAF 123/217 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DNAH17 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- EFL1 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 130/342 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EHMT2 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 550/1077 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FOLR3 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 157/437 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- GAREM2 | c.1670G>A p.W557* | Nonsense Mutation (SNP) | VAF 231/644 reads (36%) | called by muse, mutect2, varscan2
- GAREM2 | c.1671G>A p.W557* | Nonsense Mutation (SNP) | VAF 234/648 reads (36%) | called by muse, mutect2, varscan2
- GOLGA8M | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 164/712 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, varscan2
- GRIA1 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 130/215 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGSF10 | c.6056G>A p.R2019K | Missense Mutation (SNP) | VAF 144/428 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL17RE | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 109/286 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRX3 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 246/678 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LARP1B | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 130/295 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MBOAT1 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 221/442 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- MBOAT4 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 148/234 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MMP10 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 120/325 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC22 | c.4832C>T p.A1611V | Missense Mutation (SNP) | VAF 283/1120 reads (25%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.972); called by muse, mutect2
- MUC4 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 220/1044 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, varscan2
- NBEA | c.7421C>T p.P2474L | Missense Mutation (SNP) | VAF 96/175 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NCR3LG1 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 112/309 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- NID2 | c.1069+1G>A p.X357_splice | Splice Site (SNP) | VAF 126/318 reads (40%) | called by muse, mutect2, varscan2
- NLRP4 | c.2019-1G>A p.X673_splice | Splice Site (SNP) | VAF 189/240 reads (79%) | called by muse, mutect2, varscan2
- NOL4 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 89/229 reads (39%) | called by muse, mutect2, varscan2
- NOX3 | c.1012T>C p.F338L | Missense Mutation (SNP) | VAF 214/521 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR10A5 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 130/319 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10G3 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 104/310 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- OR2A12 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 176/670 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR2T6 | c.831T>A p.F277L | Missense Mutation (SNP) | VAF 307/701 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- OR52A5 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 178/468 reads (38%) | called by muse, mutect2, varscan2
- OR8S1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 118/357 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOGL | c.1276T>G p.C426G (on ENST00000547103; = p.C417G on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK5 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 123/179 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDZD2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 195/523 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PFKFB4 | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 91/161 reads (57%) | called by muse, mutect2, varscan2
- PTPRT | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RAB6D | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 162/529 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RGS7 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 116/322 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROBO4 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 203/548 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- RUNX1T1 | c.213T>A p.F71L (on ENST00000265814 / NM_001198628.1; = p.F44L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SACS | c.8021T>G p.F2674C | Missense Mutation (SNP) | VAF 196/299 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SH2D3A | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 231/597 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC12A5 | c.205G>A p.A69T (on ENST00000454036 / NM_001134771.2; = p.A46T on NM_020708.5) | Missense Mutation (SNP) | VAF 123/302 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SLTM | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 137/354 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SMOC1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 123/321 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SORCS3 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 114/322 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- STARD10 | c.356-2_356del p.X119_splice | Splice Site (DEL) | VAF 74/220 reads (34%) | called by pindel, varscan2
- STXBP5L | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TADA2B | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 188/529 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TBX15 | c.1640C>T p.P547L (on ENST00000369429 / NM_001330677.2; = p.P441L on NM_152380.3) | Missense Mutation (SNP) | VAF 209/528 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TENM1 | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 216/277 reads (78%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TINAG | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TP73 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTC6 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 115/361 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TTN | c.25093G>A p.E8365K (on ENST00000591111; = p.E7438K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 208/564 reads (37%) | PolyPhen benign (0.055); called by muse, mutect2, varscan2
- UBA6 | c.806T>A p.F269Y | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- URB2 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 163/428 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZDBF2 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 125/375 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ZDHHC16 | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 157/395 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ZNF37A | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 144/374 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ZNF98 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AADACL2 | c.501T>C p.F167= | Silent (SNP) | VAF 154/530 reads (29%) | catalogued as rs945745607; called by muse, mutect2
- AADACL3 | c.366G>A p.G122= | Silent (SNP) | VAF 145/356 reads (41%) | catalogued as rs529074360, COSV100206561; called by muse, mutect2, varscan2
- ABCG8 | c.1536G>A p.G512= | Silent (SNP) | VAF 199/481 reads (41%) | called by muse, mutect2, varscan2
- AC011005.1 | c.816G>A p.K272= | Silent (SNP) | VAF 491/861 reads (57%) | called by muse, mutect2, varscan2
- AC013477.1 | c.2487C>T p.D829= | Silent (SNP) | VAF 96/299 reads (32%) | called by muse, mutect2, varscan2
- ACSM2B | c.294G>T p.S98= | Silent (SNP) | VAF 104/264 reads (39%) | called by muse, mutect2, varscan2
- AHNAK2 | c.3324G>A p.L1108= | Silent (SNP) | VAF 227/606 reads (37%) | called by muse, mutect2, varscan2
- AKR1D1 | c.354C>T p.I118= | Silent (SNP) | VAF 93/370 reads (25%) | catalogued as rs867383157; called by muse, mutect2, varscan2
- ANAPC5 | c.1920C>T p.A640= | Silent (SNP) | VAF 93/278 reads (33%) | catalogued as rs768519725; called by muse, mutect2, varscan2
- ANKRD7 | c.642T>G p.G214= | Silent (SNP) | VAF 131/591 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.1254C>T p.V418= | Silent (SNP) | VAF 137/353 reads (39%) | catalogued as rs777649802, COSV52807324; called by muse, mutect2, varscan2
- ARMC8 | c.384C>T p.C128= (on ENST00000469044 / NM_001363941.2; = p.C114= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 145/371 reads (39%) | catalogued as rs747253917; called by muse, mutect2, varscan2
- ATP2B2 | c.1536G>A p.E512= (on ENST00000352432; = p.E478= on NM_001683.5) | Silent (SNP) | VAF 149/356 reads (42%) | called by muse, mutect2, varscan2
- BEND4 | c.1542C>T p.I514= | Silent (SNP) | VAF 145/441 reads (33%) | catalogued as rs748469545, COSV72469042; called by muse, mutect2, varscan2
- C16orf96 | c.322C>T p.L108= | Silent (SNP) | VAF 200/515 reads (39%) | called by muse, mutect2, varscan2
- CABP1 | c.1065G>A p.G355= (on ENST00000316803 / NM_001033677.1; = p.G152= on NM_004276.5) | Silent (SNP) | VAF 122/293 reads (42%) | catalogued as COSV56459595; called by muse, mutect2, varscan2
- CADPS2 | c.879C>T p.F293= | Silent (SNP) | VAF 72/240 reads (30%) | catalogued as rs1375845030, COSV57377270, COSV57391060; called by muse, mutect2, varscan2
- CARMIL3 | c.1932G>A p.A644= | Silent (SNP) | VAF 163/456 reads (36%) | catalogued as rs935360913; called by muse, mutect2, varscan2
- CCDC116 | c.198C>T p.H66= | Silent (SNP) | VAF 203/518 reads (39%) | catalogued as rs1257855305, COSV53037380; called by muse, mutect2, varscan2
- CCDC88C | c.36C>T p.F12= | Silent (SNP) | VAF 168/442 reads (38%) | catalogued as rs750911195; called by muse, mutect2, varscan2
- CDHR2 | c.3903C>T p.T1301= | Silent (SNP) | VAF 188/520 reads (36%) | called by muse, mutect2, varscan2
- CFAP77 | c.381G>A p.G127= | Silent (SNP) | VAF 89/169 reads (53%) | catalogued as rs1445273243; called by muse, mutect2, varscan2
- CSMD1 | c.3153C>T p.V1051= (on ENST00000520002; = p.V1050= on NM_033225.6) | Silent (SNP) | VAF 128/207 reads (62%) | catalogued as rs781624476; called by muse, mutect2, varscan2
- CTRC | c.204C>T p.F68= | Silent (SNP) | VAF 76/227 reads (33%) | catalogued as rs773793601, COSV65621345; called by muse, mutect2, varscan2
- DCAF8L2 | c.1191G>A p.R397= | Silent (SNP) | VAF 172/250 reads (69%) | catalogued as COSV70550900; called by muse, mutect2, varscan2
- ELAPOR1 | c.2910G>A p.E970= | Silent (SNP) | VAF 175/509 reads (34%) | catalogued as rs758471598; called by muse, mutect2, varscan2
- ELOVL6 | c.102C>T p.F34= | Silent (SNP) | VAF 80/231 reads (35%) | called by muse, mutect2, varscan2
- EMB | c.438G>A p.E146= | Silent (SNP) | VAF 65/231 reads (28%) | catalogued as COSV57484272; called by muse, mutect2, varscan2
- ENAM | c.192C>T p.N64= | Silent (SNP) | VAF 84/272 reads (31%) | called by muse, mutect2, varscan2
- FADS3 | c.606C>T p.F202= | Silent (SNP) | VAF 129/390 reads (33%) | catalogued as rs115282539; called by muse, mutect2, varscan2
- FAM83C | c.594C>T p.V198= | Silent (SNP) | VAF 177/459 reads (39%) | catalogued as rs1210204275, COSV65584530; called by muse, mutect2, varscan2
- FANCC | c.156G>A p.L52= | Silent (SNP) | VAF 97/145 reads (67%) | called by muse, mutect2, varscan2
- FAT3 | c.3894G>A p.G1298= | Silent (SNP) | VAF 149/366 reads (41%) | called by muse, mutect2, varscan2
- FRMD7 | c.177T>A p.L59= | Silent (SNP) | VAF 71/97 reads (73%) | called by muse, mutect2, varscan2
- GDPGP1 | c.687C>T p.P229= | Silent (SNP) | VAF 134/567 reads (24%) | catalogued as rs1389698423, COSV61575818; called by muse, mutect2, varscan2
- GLP1R | c.48G>A p.G16= | Silent (SNP) | VAF 390/729 reads (53%) | called by muse, mutect2, varscan2
- GLRA3 | c.189C>T p.P63= | Silent (SNP) | VAF 84/148 reads (57%) | catalogued as COSV99927150; called by muse, mutect2, varscan2
- HAS1 | c.456C>T p.F152= | Silent (SNP) | VAF 453/595 reads (76%) | called by muse, mutect2, varscan2
- HLA-DQB2 | c.387C>T p.S129= | Silent (SNP) | VAF 169/898 reads (19%) | called by muse, mutect2, varscan2
- ICAM5 | c.588C>T p.F196= | Silent (SNP) | VAF 163/464 reads (35%) | catalogued as COSV55748939; called by muse, mutect2, varscan2
- IGHV1-2 | c.120C>T p.S40= | Silent (SNP) | VAF 193/551 reads (35%) | catalogued as rs374924678; called by muse, mutect2, varscan2
- IGHV1-46 | c.24C>T p.F8= | Silent (SNP) | VAF 124/290 reads (43%) | called by muse, mutect2, varscan2
- IGHV3OR15-7 | c.273C>T p.I91= | Silent (SNP) | VAF 139/318 reads (44%) | called by muse, mutect2, varscan2
- ITPR1 | c.4821C>T p.I1607= (on ENST00000354582; = p.I1592= on NM_002222.7) | Silent (SNP) | VAF 94/287 reads (33%) | catalogued as rs746194855; called by muse, mutect2, varscan2
- KCNK16 | c.900C>T p.F300= | Silent (SNP) | VAF 143/452 reads (32%) | catalogued as COSV100949121; called by muse, mutect2, varscan2
- KIAA1549 | c.5754C>T p.L1918= (on ENST00000422774 / NM_001164665.2; = p.L1902= on NM_020910.3) | Silent (SNP) | VAF 262/940 reads (28%) | called by muse, mutect2, varscan2
- KIF16B | c.1911G>A p.V637= | Silent (SNP) | VAF 166/459 reads (36%) | called by muse, mutect2, varscan2
- KLHL38 | c.699C>T p.H233= | Silent (SNP) | VAF 179/517 reads (35%) | called by muse, mutect2, varscan2
- LILRB1 | c.750C>T p.L250= (on ENST00000427581; = p.L214= on NM_006669.6) | Silent (SNP) | VAF 284/376 reads (76%) | catalogued as COSV61121811; called by muse, varscan2
- LIMS2 | c.873C>T p.T291= (on ENST00000355119 / NM_001161403.3; = p.T315= on NM_017980.4) | Silent (SNP) | VAF 126/346 reads (36%) | called by muse, mutect2, varscan2
- LRRC23 | c.708C>T p.T236= | Silent (SNP) | VAF 169/437 reads (39%) | catalogued as rs782277388; called by muse, mutect2, varscan2
- MKS1 | c.673C>T p.L225= | Silent (SNP) | VAF 107/286 reads (37%) | catalogued as rs370632053, COSV100439734; called by muse, mutect2, varscan2
- MUC16 | c.41337G>A p.S13779= | Silent (SNP) | VAF 170/437 reads (39%) | catalogued as rs368301608; called by muse, mutect2, varscan2
- MUC16 | c.19107G>A p.R6369= | Silent (SNP) | VAF 148/411 reads (36%) | called by muse, mutect2, varscan2
- MUC22 | c.4833C>T p.A1611= | Silent (SNP) | VAF 286/1120 reads (26%) | called by muse, mutect2
- N4BP2L1 | c.312A>G p.R104= | Silent (SNP) | VAF 103/151 reads (68%) | called by muse, mutect2, varscan2
- NRXN3 | c.387C>T p.I129= (on ENST00000557594 / NM_001272020.2; = p.I761= on NM_004796.6) | Silent (SNP) | VAF 25/530 reads (5%) | catalogued as rs1410795915, COSV99820160; called by muse, mutect2
- OBSCN | c.12018T>A p.G4006= | Silent (SNP) | VAF 184/523 reads (35%) | called by muse, mutect2, varscan2
- OR10J3 | c.36C>T p.F12= | Silent (SNP) | VAF 116/289 reads (40%) | catalogued as COSV59955527; called by muse, mutect2, varscan2
- OR13C4 | c.43C>T p.L15= | Silent (SNP) | VAF 109/179 reads (61%) | called by muse, mutect2, varscan2
- OR4C11 | c.561C>T p.C187= | Silent (SNP) | VAF 172/225 reads (76%) | catalogued as rs1381869714; called by muse, mutect2, varscan2
- OR51B2 | c.789G>A p.G263= | Silent (SNP) | VAF 167/381 reads (44%) | catalogued as rs140495971, COSV60916129; called by muse, mutect2, varscan2
- OR5BS1P | c.88C>T p.L30= | Silent (SNP) | VAF 179/463 reads (39%) | called by muse, mutect2, varscan2
- OR5R1 | c.642C>T p.V214= | Silent (SNP) | VAF 150/441 reads (34%) | catalogued as rs546998737; called by muse, mutect2, varscan2
- OR6P1 | c.384A>T p.G128= | Silent (SNP) | VAF 171/412 reads (42%) | called by muse, mutect2, varscan2
- OR8B4 | c.150G>A p.G50= | Silent (SNP) | VAF 169/479 reads (35%) | called by muse, mutect2, varscan2
- P2RY8 | c.900C>T p.F300= | Silent (SNP) | VAF 223/631 reads (35%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.175C>T p.L59= | Silent (SNP) | VAF 188/598 reads (31%) | catalogued as rs1423038404; called by muse, mutect2, varscan2
- PLA2G4A | c.1131C>T p.V377= | Silent (SNP) | VAF 128/349 reads (37%) | catalogued as rs546228398; called by muse, mutect2, varscan2
- PLAGL1 | c.60G>A p.T20= | Silent (SNP) | VAF 166/383 reads (43%) | catalogued as rs201628824; called by muse, mutect2, varscan2
- POSTN | c.1488G>A p.E496= | Silent (SNP) | VAF 146/241 reads (61%) | catalogued as rs1306144614; called by muse, mutect2, varscan2
- PPARG | c.1134G>A p.R378= (on ENST00000287820 / NM_015869.5; = p.R348= on NM_005037.7) | Silent (SNP) | VAF 136/357 reads (38%) | called by muse, mutect2, varscan2
- PROCR | c.501G>A p.Q167= | Silent (SNP) | VAF 191/506 reads (38%) | called by muse, varscan2
- PRTG | c.2889C>T p.L963= | Silent (SNP) | VAF 126/388 reads (32%) | called by muse, mutect2, varscan2
- PTPRU | c.3168C>T p.V1056= | Silent (SNP) | VAF 204/533 reads (38%) | called by muse, mutect2, varscan2
- RBP3 | c.357G>A p.R119= | Silent (SNP) | VAF 209/630 reads (33%) | catalogued as rs138261581; called by muse, mutect2, varscan2
- SCAMP2 | c.138G>A p.A46= | Silent (SNP) | VAF 142/348 reads (41%) | catalogued as rs781174592; called by muse, mutect2, varscan2
- SLC28A3 | c.1939C>T p.L647= | Silent (SNP) | VAF 88/151 reads (58%) | called by muse, mutect2, varscan2
- SLC35F3 | c.81C>T p.S27= | Silent (SNP) | VAF 127/325 reads (39%) | catalogued as rs369506915; called by muse, mutect2, varscan2
- SLCO2B1 | c.1191C>T p.F397= | Silent (SNP) | VAF 242/558 reads (43%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.2241C>T p.F747= | Silent (SNP) | VAF 180/426 reads (42%) | catalogued as rs1294938615, COSV52655710; called by muse, mutect2, varscan2
- SORD | c.297C>T p.P99= | Silent (SNP) | VAF 113/311 reads (36%) | catalogued as COSV51043006; called by muse, mutect2, varscan2
- SOX17 | c.789G>A p.P263= | Silent (SNP) | VAF 38/710 reads (5%) | called by muse, mutect2
- SPRR2D | c.156G>A p.Q52= | Silent (SNP) | VAF 249/706 reads (35%) | called by muse, mutect2, varscan2
- TADA2B | c.387C>T p.P129= | Silent (SNP) | VAF 183/528 reads (35%) | called by muse, mutect2, varscan2
- TAS2R7 | c.579C>T p.P193= | Silent (SNP) | VAF 245/628 reads (39%) | catalogued as COSV99553555; called by muse, mutect2, varscan2
- TCAF2 | c.906G>A p.G302= | Silent (SNP) | VAF 209/597 reads (35%) | called by muse, mutect2, varscan2
- THEMIS | c.1071C>T p.I357= | Silent (SNP) | VAF 188/506 reads (37%) | catalogued as rs146173025, COSV64069646; called by muse, mutect2, varscan2
- TPTE2 | c.454C>T p.L152= | Silent (SNP) | VAF 77/165 reads (47%) | catalogued as rs776437343; called by muse, mutect2, varscan2
- TRAV9-1 | c.114G>A p.L38= | Silent (SNP) | VAF 135/373 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.12456G>A p.L4152= (on ENST00000591111; = p.L4106= on NM_003319.4) | Silent (SNP) | VAF 168/416 reads (40%) | catalogued as COSV59908504, COSV60386544; called by muse, mutect2, varscan2
- VCAM1 | c.954C>T p.S318= | Silent (SNP) | VAF 126/342 reads (37%) | called by muse, mutect2, varscan2
- VRTN | c.1452G>A p.G484= | Silent (SNP) | VAF 224/585 reads (38%) | catalogued as COSV99832168; called by muse, mutect2, varscan2
- VWA3A | c.2862C>T p.T954= | Silent (SNP) | VAF 147/358 reads (41%) | catalogued as rs774492916; called by muse, mutect2, varscan2
- WIZ | c.5190C>T p.G1730= (on ENST00000673675 / NM_001371589.1; = p.G635= on NM_021241.3) | Silent (SNP) | VAF 211/650 reads (32%) | called by muse, mutect2, varscan2
- ZNF43 | c.633T>C p.F211= | Silent (SNP) | VAF 141/377 reads (37%) | catalogued as rs1477667138; called by muse, mutect2, varscan2
- ZNF500 | c.612C>T p.P204= | Silent (SNP) | VAF 117/377 reads (31%) | catalogued as rs1191391018; called by muse, mutect2, varscan2
- ZNF665 | c.1371C>T p.A457= (on ENST00000600412; = p.A522= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 379/489 reads (78%) | called by muse, mutect2, varscan2
- CBX2 | c.288+214C>T | Intron (SNP) | VAF 206/539 reads (38%) | catalogued as rs782298979, COSV53969845; called by muse, mutect2, varscan2
- GALNT14 | c.129+23156C>T | Intron (SNP) | VAF 125/335 reads (37%) | catalogued as rs267599342; called by muse, mutect2, varscan2
- MUC2 | chr11:1099668 G>A | 5'Flank (SNP) | VAF 188/693 reads (27%) | catalogued as rs1378734988; called by muse, mutect2, varscan2
- NPAP1L | n.303G>A | RNA (SNP) | VAF 90/273 reads (33%) | called by muse, mutect2, varscan2
- OSR2 | c.-46C>T | 5'UTR (SNP) | VAF 227/554 reads (41%) | called by muse, mutect2, varscan2
- RAPH1 | c.733-8363C>T | Intron (SNP) | VAF 135/347 reads (39%) | catalogued as rs866786008; called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1771C>T | Intron (SNP) | VAF 154/419 reads (37%) | called by muse, mutect2, varscan2
- VPS52 | c.90+136C>T | Intron (SNP) | VAF 136/576 reads (24%) | called by muse, mutect2, varscan2
- ZKSCAN5 | c.*1402C>T | 3'UTR (SNP) | VAF 77/139 reads (55%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.557-76C>T | Intron (SNP) | VAF 135/384 reads (35%) | called by muse, mutect2, varscan2
